Gene-level copy-number profile of specimen HCM-BROD-0594-C43-85M from HCMI case HCM-BROD-0594-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 75.4 years (27,524 days).
Specimen HCM-BROD-0594-C43-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 10.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4d91a2de-4acb-4bdd-be1f-1bcfc8bf1a44.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0594-C43-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,722 have no estimate.
https://portal.gdc.cancer.gov/files/3e9ef4c8-67e7-4d67-a65b-cae63c4b1221

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 3,471; copy number 2: 18,075; copy number 3: 26,668; copy number 4: 8,940; copy number 5: 1,625; copy number 6: 53; copy number 7: 29; copy number 9: 18; copy number 10: 12; copy number 14: 2.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:43,109,866–60,964,196, 8 genes: FP325317.1, FP325317.2, BX088702.1, SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 61 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:32,685,145–33,869,707, 25 genes, copy number 9–14: CNOT10, CNOT10-AS1, SUGT1P2, RPL23AP43, TRIM71, CCR4, GLB1, SEC13P1, SUMO2P10, TMPPE, RN7SL296P, CRTAP, AC112211.1, SUSD5, AC123900.1, FBXL2, UBP1, RNU7-110P, RNA5SP128, CLASP2, COX6CP10, AC112220.1, SDAD1P3, AC112220.2, PDCD6IP.
- chr3:68,975,217–69,968,336, 14 genes, copy number 7–9: EOGT, AC109587.1, TMF1, MIR3136, UBA3, ARL6IP5, LMOD3, FRMD4B, RBM43P1, AC099328.1, AC099328.2, AC104445.1, MITF, RN7SL418P.
- chr8:48,384,590–49,907,446, 22 genes, copy number 7: RPL29P19, AC041040.1, AC026904.1, AC026904.2, AC022915.2, LINC02599, LINC02847, AC022915.1, AC022915.3, EFCAB1, AC013701.1, SNAI2, AC044893.2, PPDPFL, AC044893.1, RN7SKP294, RFPL4AP7, AC090155.2, AC090155.1, PSAT1P1, AC113145.1, AC023762.1.

Autosomal genes at a single copy (total copy number 1): 1,407. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
